Somatic mutation profile of tumor specimen TCGA-AB-2886-03A (aliquot TCGA-AB-2886-03A-01W-0732-08) from TCGA case TCGA-AB-2886, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 26.0 years (9,497 days).
Specimen TCGA-AB-2886-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22a6d4df-3ade-4c86-ab62-8c5c0ded47c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2886-11A (Solid Tissue Normal), aliquot TCGA-AB-2886-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9c2a140-1316-4f95-8e18-234cff8a45ba

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTNAP5 | c.454G>T p.V152F | Missense Mutation (SNP) | VAF 78/164 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.301); catalogued as COSV70477933, COSV70519006; called by muse, mutect2, varscan2
- DNAH11 | c.8502G>T p.M2834I | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV60979972; called by muse, mutect2, varscan2
- ITPR3 | c.2461G>A p.A821T | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs747839088, COSV65405072; called by muse, varscan2
- JAK3 | c.1533G>A p.M511I | Missense Mutation (SNP) | VAF 46/297 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs752661478, COSV71685384, COSV71685422, COSV71685783; called by muse, mutect2, varscan2
- RAP1B | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51667594; called by muse, mutect2, varscan2
- RAD21 | c.1357del p.E453Sfs*3 | Frame Shift Del (DEL) | VAF 38/94 reads (40%) | called by mutect2, pindel*, varscan2*
- HIRA | c.2826C>T p.Y942= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs371591299; called by muse, mutect2
- PLA2G2A | c.93G>A p.L31= | Silent (SNP) | VAF 59/163 reads (36%) | catalogued as rs2236770, COSV100908627; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81156942 C>T | 3'Flank (SNP) | VAF 15/43 reads (35%) | catalogued as rs769526533; called by muse, mutect2, varscan2
